Somatic mutation profile of tumor specimen TCGA-37-A5EL-01A (aliquot TCGA-37-A5EL-01A-11D-A26M-08) from TCGA case TCGA-37-A5EL, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 53.0 years (19,371 days).
Specimen TCGA-37-A5EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df21498a-07af-4725-8025-bbd51b291b97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-37-A5EL-10A (Blood Derived Normal), aliquot TCGA-37-A5EL-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2c7e9a1-2c43-4256-a8c2-117deca29bc5

The open-access MAF lists 471 somatic variants for this specimen: 345 protein-altering or splice-affecting, 118 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 292, Silent 118, Frame Shift Del 19, Nonsense Mutation 18, Splice Site 8, Splice Region 5, RNA 3, In Frame Del 2, 3'UTR 2, 5'UTR 2, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 33/41 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691037, CM087281, CM159290, COSV52670715, COSV52718021, COSV53252418; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.1400A>C p.E467A | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV100588342; called by muse, mutect2, varscan2
- A2ML1 | c.1065C>A p.F355L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV55287322, COSV55298413; called by muse, mutect2, varscan2
- ACTC1 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99291526; called by muse, mutect2, varscan2
- ADAM21 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99960299; called by muse, mutect2
- ADAMTS12 | c.2881G>T p.G961C | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100710058; called by muse, mutect2, varscan2
- ADAMTS3 | c.502C>T p.L168= | Splice Region (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99709890; called by muse, mutect2, varscan2
- ADAMTS7 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101182986, COSV66306674; called by muse, mutect2, varscan2
- ADGRA2 | c.1327C>A p.L443M | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100177408; called by muse, mutect2, varscan2
- ADGRV1 | c.6193G>C p.D2065H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101315287; called by muse, mutect2
- ADRA1A | c.1339C>A p.H447N | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV99369733; called by muse, mutect2, varscan2
- AHNAK | c.15309A>T p.K5103N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99945138; called by muse, mutect2, varscan2
- AHNAK | c.2557G>C p.E853Q | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV99945139; called by muse, mutect2, varscan2
- AL592490.1 | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs138957659; called by muse, mutect2, varscan2
- ANK1 | c.1762C>A p.L588M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99223517; called by muse, mutect2, varscan2
- ANKAR | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99853765; called by muse, mutect2, varscan2
- ANKFN1 | c.1670A>T p.Y557F | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.221); catalogued as COSV100592940; called by muse, mutect2, varscan2
- ANKLE2 | c.848-1G>C p.X283_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as rs1050677626, COSV100513860; called by mutect2, varscan2
- ANKRD11 | c.3363T>A p.D1121E | Missense Mutation (SNP) | VAF 82/103 reads (80%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99967944; called by muse, mutect2, varscan2
- ANO5 | c.2590A>T p.R864* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV100201266; called by muse, mutect2, varscan2
- AOC3 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV53826401; called by muse, mutect2, varscan2
- AP002512.3 | c.837C>G p.H279Q | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV99687655; called by muse, mutect2, varscan2
- APC2 | c.3910C>A p.R1304S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.29); catalogued as rs770523255, COSV99279032; called by muse, mutect2, varscan2
- ARF5 | c.455C>G p.T152R | Missense Mutation (SNP) | VAF 89/151 reads (59%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.01); catalogued as COSV99133512, COSV99134006; called by muse, mutect2, varscan2
- ARHGEF19 | c.2255G>T p.W752L | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99579962; called by muse, mutect2, varscan2
- ARID1B | c.4804G>A p.A1602T | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99266471; called by muse, mutect2, varscan2
- ARMC7 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs752190084, COSV99822541; called by muse, mutect2, varscan2
- ARMH4 | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99957428; called by muse, mutect2, varscan2
- ASXL1 | c.2242C>G p.Q748E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.287); catalogued as COSV100037272, COSV60102679; called by muse, mutect2, varscan2
- ATP10A | c.2879C>A p.P960H | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV100790720, COSV100791699; called by muse, mutect2, varscan2
- ATP8A1 | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.732); catalogued as COSV100044557; called by muse, mutect2, varscan2
- AXDND1 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 65/373 reads (17%) | catalogued as COSV100858228, COSV62642768; called by muse, mutect2, varscan2
- AXIN1 | c.2321G>A p.G774D | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as COSV99249053; called by muse, mutect2, varscan2
- AXIN1 | c.2320G>C p.G774R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV51988088, COSV51989070, COSV99249054; called by muse, mutect2, varscan2
- BAIAP3 | c.1597C>A p.R533S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV100180942; called by muse, mutect2, varscan2
- BCO1 | c.662T>A p.V221E | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV99257300; called by muse, varscan2
- C2orf16 | c.4879G>T p.E1627* | Nonsense Mutation (SNP) | VAF 170/264 reads (64%) | catalogued as COSV100820601; called by muse, mutect2, varscan2
- CA4 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs773737207, COSV99958162; called by muse, mutect2, varscan2
- CACNA1G | c.7048G>C p.D2350H | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as COSV100660983; called by muse, mutect2, varscan2
- CALM3 | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV99355156; called by muse, mutect2, varscan2
- CARS1 | c.268T>G p.F90V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV99541794; called by muse, mutect2
- CASP8AP2 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99386681; called by muse, mutect2, varscan2
- CCDC74B | c.471del p.D158Tfs*103 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as COSV100134117; called by mutect2, pindel, varscan2
- CDH18 | c.1201G>T p.V401F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.212); catalogued as COSV56923247, COSV99931183; called by muse, mutect2, varscan2
- CDKN2A | c.134del p.G45Vfs*8 | Frame Shift Del (DEL) | VAF 75/134 reads (56%) | catalogued as COSV58685320; called by mutect2, pindel, varscan2
- CEP170B | c.3881G>A p.R1294Q (on ENST00000453495; = p.R1223Q on NM_015005.3) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.056); catalogued as rs375522520; called by muse, mutect2, varscan2
- CEP192 | c.3851A>T p.N1284I | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100380388; called by muse, mutect2, varscan2
- CFAP157 | c.850C>A p.Q284K | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1564366189, COSV100076637; called by muse, mutect2, varscan2
- CFAP61 | c.1417G>T p.D473Y | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55637439, COSV99842583; called by muse, mutect2, varscan2
- CHD7 | c.1447G>T p.V483F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.396); catalogued as COSV101417930; called by muse, mutect2, varscan2
- CHEK1 | c.663G>T p.W221C | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99629394, COSV99629721; called by muse, mutect2, varscan2
- CHL1 | c.2214G>T p.M738I (on ENST00000397491 / NM_001253387.1; = p.M754I on NM_006614.4) | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV99849679; called by muse, mutect2
- CLEC1B | c.506T>A p.V169D | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV100045914; called by muse, mutect2, varscan2
- CLVS1 | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV100369276; called by muse, mutect2, varscan2
- CNDP2 | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV100158855; called by muse, mutect2, varscan2
- CNNM2 | c.2138A>G p.Y713C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100881784; called by muse, mutect2, varscan2
- CNTN6 | c.801C>A p.S267R | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT tolerated (0.69); PolyPhen benign (0.301); catalogued as rs777348065, COSV100609667; called by muse, mutect2, varscan2
- CNTNAP2 | c.2044T>A p.C682S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661555; called by muse, mutect2, varscan2
- COL28A1 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV101258235; called by muse, mutect2
- COL3A1 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV58583826; called by muse, mutect2, varscan2
- COL3A1 | c.2198G>A p.G733D | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); catalogued as COSV100482182, COSV100482379; called by muse, mutect2, varscan2
- COL3A1 | c.2366G>T p.G789V | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482185; called by muse, mutect2, varscan2
- CPB2 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99472871; called by muse, mutect2, varscan2
- CPN2 | c.861C>A p.H287Q | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100102762; called by muse, mutect2
- CRB1 | c.1433C>G p.S478C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV100957598; called by muse, mutect2, varscan2
- CSTF2T | c.1554G>T p.M518I | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100484044; called by muse, mutect2, varscan2
- CTSF | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362151153, COSV100074029; called by muse, varscan2
- CTSL | c.397-1G>T p.X133_splice | Splice Site (SNP) | VAF 50/180 reads (28%) | catalogued as COSV100446570; called by muse, mutect2, varscan2
- CXCR2 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100578737; called by muse, mutect2, varscan2
- CXorf66 | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 99/119 reads (83%) | SIFT tolerated (0.62); PolyPhen benign (0.084); catalogued as COSV100983801; called by muse, mutect2, varscan2
- CYP4F2 | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.384); catalogued as COSV99171030; called by muse, mutect2, varscan2
- CYTIP | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99938591; called by muse, mutect2, varscan2
- DBR1 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99604328; called by muse, mutect2, varscan2
- DCLRE1C | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs747849702, COSV100739669; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DENND5A | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.933); catalogued as COSV100063804; called by muse, mutect2, varscan2
- DENND5B | c.3754C>T p.R1252* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs981331087, COSV60905681; called by muse, mutect2, varscan2
- DIS3L2 | c.845T>A p.L282H | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV56062000, COSV99804992; called by muse, mutect2, varscan2
- DLG1 | c.2299G>C p.E767Q (on ENST00000419354 / NM_001290983.1; = p.E789Q on NM_004087.2) | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV100014407; called by muse, mutect2, varscan2
- DMBT1 | c.5526G>T p.E1842D (on ENST00000338354 / NM_001377530.1; = p.E1085D on NM_004406.3) | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100351782; called by muse, mutect2, varscan2
- DNAH11 | c.5162C>A p.A1721D | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100176127; called by muse, mutect2, varscan2
- DNM1 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 112/435 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100359318, COSV57850288; called by muse, mutect2, varscan2
- EEF1AKNMT | c.926G>T p.R309L (on ENST00000361735 / NM_015935.5; = p.R223L on NM_014955.3) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV100675721; called by muse, mutect2, varscan2
- EEF1G | c.787A>C p.M263L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100239979; called by muse, mutect2, varscan2
- EFCAB3 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100539991; called by muse, mutect2, varscan2
- EFEMP1 | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.031); catalogued as rs148488868; called by muse, mutect2, varscan2
- EMB | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV100296536; called by muse, mutect2, varscan2
- EMP3 | c.410A>G p.Y137C | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1325206464, COSV99506873; called by muse, mutect2, varscan2
- ERVW-1 | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.075); catalogued as COSV101423795; called by muse, mutect2, varscan2
- ERVW-1 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.392); catalogued as COSV101423796; called by muse, mutect2, varscan2
- F5 | c.1090G>C p.A364P | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100888814; called by muse, mutect2, varscan2
- FAM107A | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348360231, COSV100723896; called by muse, mutect2, varscan2
- FAM135B | c.1628C>A p.P543Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV99417167, COSV99425393; called by muse, mutect2, varscan2
- FAM170A | c.984G>T p.R328S | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.662); catalogued as COSV100088633, COSV58924153; called by muse, mutect2, varscan2
- FANCI | c.1541G>A p.R514K | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT tolerated (0.75); PolyPhen benign (0.138); catalogued as COSV100167363; called by muse, mutect2, varscan2
- FAT1 | c.12487G>T p.E4163* | Nonsense Mutation (SNP) | VAF 55/65 reads (85%) | catalogued as COSV101498596; called by muse, mutect2, varscan2
- FBN2 | c.3233A>C p.K1078T | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as COSV99324033; called by muse, mutect2, varscan2
- FCHSD2 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV60811576; called by muse, mutect2, varscan2
- FCRL2 | c.550C>G p.H184D | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV100829776; called by muse, mutect2, varscan2
- FERMT3 | c.450G>C p.K150N | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.383); catalogued as rs12794742, COSV99656201; called by muse, varscan2
- FLG2 | c.4231C>G p.Q1411E | Missense Mutation (SNP) | VAF 109/322 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV101165533; called by muse, mutect2, varscan2
- FMN2 | c.1193C>A p.P398H | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV100141962; called by muse, mutect2, varscan2
- FOSL1 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100440780; called by muse, mutect2
- G6PC2 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99960602; called by muse, mutect2, varscan2
- GC | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99909289; called by muse, mutect2, varscan2
- GCH1 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99581496; called by muse, mutect2, varscan2
- GDF7 | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV99693938; called by muse, mutect2
- GID8 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV99824024; called by muse, mutect2, varscan2
- GJD2 | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV99290517; called by muse, mutect2, varscan2
- GK2 | c.983T>C p.V328A | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV100725840; called by muse, mutect2, varscan2
- GLYR1 | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 123/279 reads (44%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.548); catalogued as COSV100423949; called by muse, mutect2, varscan2
- GPRC5C | c.484G>A p.A162T (on ENST00000652232; = p.A117T on NM_018653.4) | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as COSV100702754; called by muse, mutect2, varscan2
- GRB7 | c.935A>G p.H312R | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV100485320; called by muse, mutect2, varscan2
- GRK1 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.216); catalogued as COSV100175211; called by muse, mutect2, varscan2
- GRM7 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 62/85 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762191015, COSV63139895; called by muse, mutect2, varscan2
- GRM7 | c.1546C>G p.R516G | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV100735140, COSV63130661; called by muse, mutect2, varscan2
- HBD | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.302); catalogued as COSV53082140, COSV99496475; called by muse, mutect2, varscan2
- HEATR1 | c.4886A>G p.Q1629R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.218); catalogued as COSV100857276; called by muse, mutect2, varscan2
- HECW1 | c.3354G>T p.K1118N | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV101222483; called by muse, mutect2, varscan2
- HLX | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100854423; called by muse, mutect2, varscan2
- HPD | c.141C>A p.Y47* | Nonsense Mutation (SNP) | VAF 27/122 reads (22%) | catalogued as COSV56643086; called by muse, mutect2, varscan2
- HSD17B1 | c.90C>A p.S30R | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99864567; called by muse, mutect2, varscan2
- IGHV3-30 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs778939031; called by muse, mutect2
- IGKV1D-42 | c.134G>C p.C45S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs192596253; called by muse, mutect2, varscan2
- IGSF10 | c.5608C>A p.P1870T | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99176528; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.079); catalogued as COSV100144459; called by muse, mutect2, varscan2
- INHBB | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99735532; called by muse, mutect2, varscan2
- INSRR | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV100946996; called by muse, mutect2, varscan2
- ITGB3 | c.2015-1G>C p.X672_splice | Splice Site (SNP) | VAF 19/56 reads (34%) | catalogued as COSV101457488; called by muse, mutect2, varscan2
- JPH2 | c.779C>G p.A260G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100881549; called by muse, mutect2, varscan2
- KANSL3 | c.1955C>T p.S652F (on ENST00000666923 / NM_001349262.2; = p.S626F on NM_001115016.3) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.768); catalogued as rs1260671280, COSV100830831; called by muse, mutect2, varscan2
- KCNH4 | c.1519C>G p.P507A | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99236558; called by muse, mutect2, varscan2
- KCNT2 | c.2975A>G p.H992R | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99650717; called by muse, mutect2, varscan2
- KIF21A | c.4729C>T p.Q1577* (on ENST00000361418 / NM_001378440.1; = p.Q1564* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as COSV62771467; called by muse, mutect2, varscan2
- KIF26B | c.844G>C p.G282R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as CM1410412, COSV101313704; called by muse, mutect2, varscan2
- KIF2B | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52128780; called by muse, mutect2
- KLF11 | c.166T>A p.S56T | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV100007605; called by muse, mutect2, varscan2
- KLHL1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100916836; called by muse, mutect2, varscan2
- KMT2D | c.5564C>T p.P1855L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99976483; called by muse, mutect2, varscan2
- KMT2D | c.2129C>G p.P710R | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs758912919, COSV99976484; called by muse, mutect2, varscan2
- KNG1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 106/134 reads (79%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.738); catalogued as COSV99404934; called by muse, mutect2, varscan2
- LAMA3 | c.6214G>C p.E2072Q (on ENST00000313654 / NM_198129.4; = p.E463Q on NM_000227.6) | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV99333652; called by muse, mutect2, varscan2
- LAPTM4B | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs976097984, COSV100806173; called by muse, mutect2, varscan2
- LARP1 | c.2963A>G p.Y988C (on ENST00000518297 / NM_033551.3; = p.Y911C on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100303298; called by muse, mutect2, varscan2
- LCT | c.3680A>T p.E1227V | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); catalogued as COSV99928258; called by muse, mutect2, varscan2
- LGR5 | c.2163C>A p.S721R | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV99877304; called by muse, mutect2
- LINGO4 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs760270741, COSV100917345; called by muse, mutect2, varscan2
- LMAN1L | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV100547502; called by muse, mutect2, varscan2
- LOXL3 | c.2175C>A p.H725Q | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as COSV99239365; called by muse, mutect2, varscan2
- LRP3 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53504746, COSV99471863; called by muse, mutect2, varscan2
- LRRC4 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 126/216 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1436155405, COSV50813502; called by muse, mutect2, varscan2
- LRRC4C | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99536535; called by muse, mutect2, varscan2
- LRRC4C | c.20T>A p.L7* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99536543; called by muse, mutect2, varscan2
- LRRN2 | c.673C>A p.L225M | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100912699; called by muse, mutect2, varscan2
- LRRTM1 | c.1397C>A p.T466K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0.194); catalogued as COSV54440978, COSV99701541; called by muse, mutect2, varscan2
- MAGI2 | c.3400C>A p.L1134M | Missense Mutation (SNP) | VAF 154/189 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100831771, COSV62698863; called by muse, mutect2, varscan2
- MAGI2 | c.998C>A p.P333Q | Missense Mutation (SNP) | VAF 85/100 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831774, COSV62653837; called by muse, mutect2, varscan2
- MAP2 | c.1262A>G p.Q421R | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV99557168; called by muse, mutect2, varscan2
- MAP3K21 | c.1724G>T p.R575L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV100786060; called by muse, mutect2, varscan2
- MAPK15 | c.1273G>C p.G425R | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100567632; called by muse, mutect2, varscan2
- MFSD2B | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100600936; called by muse, mutect2, varscan2
- MGAT4C | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100152445; called by muse, mutect2, varscan2
- MSC | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 99/518 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs779458176, COSV57697499; called by muse, mutect2, varscan2
- MSRB2 | c.355A>T p.T119S | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV100919684; called by muse, mutect2, varscan2
- MTR | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100855666; called by muse, mutect2, varscan2
- MUC16 | c.36037T>A p.L12013M | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as COSV101197350; called by muse, varscan2
- MUC5B | c.12925C>G p.P4309A | Missense Mutation (SNP) | VAF 106/272 reads (39%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.16); catalogued as COSV71590273; called by muse, mutect2, varscan2
- MYH6 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs768924353, COSV100676153, COSV62451798; called by muse, mutect2, varscan2
- MYO18B | c.4091T>A p.L1364Q | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100122238; called by muse, mutect2, varscan2
- NCAM1 | c.1820C>A p.P607Q (on ENST00000316851 / NM_181351.5; = p.P597Q on NM_000615.7) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100376784; called by muse, mutect2, varscan2
- NCK2 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51895591; called by muse, mutect2, varscan2
- NFAT5 | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100590306; called by muse, mutect2, varscan2
- NIBAN1 | c.2725G>T p.D909Y | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as COSV100836129; called by muse, mutect2, varscan2
- NLRP14 | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV100204410; called by muse, mutect2, varscan2
- NMBR | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99237062; called by muse, mutect2, varscan2
- NOL8 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100694395; called by muse, varscan2
- NOS1AP | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 144/202 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100722719; called by muse, mutect2, varscan2
- NOS3 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52493104; called by muse, mutect2, varscan2
- NPAS4 | c.1549G>T p.A517S | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); catalogued as COSV100214688; called by muse, mutect2, varscan2
- NRXN3 | c.1130C>T p.S377L (on ENST00000335750 / NM_001330195.2; = p.S4L on NM_004796.6) | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs867067203, COSV59716282; called by muse, mutect2, varscan2
- NRXN3 | c.2601C>A p.N867K (on ENST00000335750 / NM_001330195.2; = p.N494K on NM_004796.6) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.085); catalogued as COSV100199382; called by muse, mutect2, varscan2
- NUP188 | c.797+1G>C p.X266_splice | Splice Site (SNP) | VAF 27/102 reads (26%) | catalogued as COSV101001115; called by muse, mutect2, varscan2
- OBSCN | c.15328G>T p.V5110L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1269267503, COSV99470788; called by muse, mutect2, varscan2
- OLFML2B | c.392A>G p.D131G | Missense Mutation (SNP) | VAF 116/151 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99667909; called by muse, mutect2, varscan2
- OR10V1 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100275449; called by muse, mutect2, varscan2
- OR2A25 | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs377302946; called by muse, mutect2, varscan2
- OR2L13 | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV63547893, COSV63554410; called by muse, mutect2, varscan2
- OR2T3 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100612987, COSV62082421; called by muse, mutect2, varscan2
- OR2T4 | c.435C>G p.F145L | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV63543478, COSV63543719; called by muse, mutect2, varscan2
- OR4B1 | c.593T>G p.L198W | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100535455; called by muse, mutect2, varscan2
- OR4C13 | c.549C>G p.I183M | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.392); catalogued as COSV101634129, COSV101634132; called by muse, mutect2, varscan2
- OR4D10 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as rs554025037, COSV101596988; called by muse, mutect2, varscan2
- OR51G2 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV100432005; called by muse, mutect2, varscan2
- OR51T1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs368635635, COSV100434241, COSV59024827; called by muse, mutect2, varscan2
- OR5J2 | c.541A>G p.I181V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100398857; called by muse, mutect2, varscan2
- OR6K3 | c.767G>T p.C256F (on ENST00000368146; = p.C240F on NM_001005327.2) | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933818, COSV63746290; called by muse, mutect2
- OR6N2 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV100209880; called by muse, mutect2
- OTOA | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV99623310; called by muse, mutect2, varscan2
- P2RX7 | c.1188G>T p.P396= | Splice Region (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99947358; called by muse, mutect2, varscan2
- PCDH10 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.711); catalogued as COSV52096187, COSV99992589; called by muse, mutect2, varscan2
- PCDH15 | c.3495A>C p.R1165S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV100213240; called by muse, mutect2, varscan2
- PCDH15 | c.3494G>T p.R1165I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100213245, COSV100229870; called by muse, mutect2, varscan2
- PCDH15 | c.1373del p.G458Vfs*24 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as COSV57295026; called by mutect2, varscan2
- PCDH9 | c.1355C>A p.T452N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.88); catalogued as rs774953649, COSV100117345; called by muse, mutect2, varscan2
- PCDHA2 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 96/142 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100973327, COSV65366721; called by muse, mutect2, varscan2
- PCDHA7 | c.1893del p.S632Afs*6 | Frame Shift Del (DEL) | VAF 51/102 reads (50%) | catalogued as COSV65345082; called by mutect2, pindel, varscan2
- PCDHA7 | c.2261G>T p.R754M | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV100970302; called by muse, mutect2, varscan2
- PCDHB6 | c.1079A>G p.E360G | Missense Mutation (SNP) | VAF 48/59 reads (81%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV99169873; called by muse, mutect2, varscan2
- PCDHGB7 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99528157; called by muse, mutect2, varscan2
- PDCL3 | c.315A>T p.E105D | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99959379; called by muse, mutect2, varscan2
- PHKA2 | c.277A>T p.M93L | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV101176542; called by muse, mutect2, varscan2
- PHLDB1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100616165; called by muse, mutect2, varscan2
- PIK3C2G | c.2786A>G p.D929G (on ENST00000676171; = p.D888G on NM_004570.5) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV99848613; called by muse, varscan2
- PIK3CG | c.246C>G p.S82R | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV100782399; called by muse, mutect2, varscan2
- PIK3R6 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100265992; called by muse, mutect2, varscan2
- PITX2 | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 56/69 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100721452, COSV61585943; called by muse, mutect2, varscan2
- PKP3 | c.1134G>T p.Q378H | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100520637; called by muse, mutect2, varscan2
- PLA2G2D | c.210C>A p.C70* | Nonsense Mutation (SNP) | VAF 24/36 reads (67%) | catalogued as COSV100907988; called by muse, mutect2, varscan2
- PLCH1 | c.2276T>C p.I759T (on ENST00000340059 / NM_001130960.2; = p.I771T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58186755; called by muse, mutect2, varscan2
- PLG | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV99804118, COSV99804991; called by muse, mutect2, varscan2
- PLPP5 | c.463+5G>T | Splice Region (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100394773; called by muse, mutect2, varscan2
- PLXNA4 | c.1603A>C p.T535P | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.433); catalogued as COSV100321799; called by muse, mutect2, varscan2
- PNLIP | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100981572; called by muse, mutect2, varscan2
- PNO1 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99718088; called by muse, mutect2, varscan2
- POSTN | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65712111; called by muse, mutect2, varscan2
- PPP4R4 | c.1981G>C p.D661H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100428150; called by muse, mutect2, varscan2
- PRKAR1A | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV100675026; called by muse, mutect2, varscan2
- PRKDC | c.5539G>C p.A1847P | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as COSV100037827; called by muse, mutect2, varscan2
- PRLHR | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1379050023, COSV99492580; called by muse, mutect2, varscan2
- PRLHR | c.1026C>A p.F342L | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV53303452, COSV99492581; called by muse, mutect2, varscan2
- PRUNE2 | c.7207G>T p.E2403* | Nonsense Mutation (SNP) | VAF 57/91 reads (63%) | catalogued as COSV100944167; called by muse, mutect2, varscan2
- PRX | c.4349C>T p.P1450L | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as rs369949312, COSV99396659; called by muse, mutect2, varscan2
- PSCA | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as rs1554638441, COSV100008157; called by muse, mutect2, varscan2
- PSD | c.1484C>A p.P495Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99192094; called by muse, mutect2, varscan2
- PSD | c.1483C>G p.P495A | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs770161929, COSV99192095; called by muse, mutect2, varscan2
- PYDC2 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.047); catalogued as COSV101573345; called by muse, mutect2
- PYGB | c.2415C>A p.N805K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99404742; called by muse, mutect2, varscan2
- QKI | c.478G>C p.A160P | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99273919; called by muse, mutect2, varscan2
- RAB3IP | c.185C>A p.S62* (on ENST00000550536 / NM_175623.4; = p.S46* on NM_022456.5) | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99922839; called by muse, mutect2, varscan2
- RABL3 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52206347; called by muse, mutect2, varscan2
- RELN | c.4703C>T p.A1568V | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs767133532, COSV100631893; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIPPLY2 | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100859424; called by muse, mutect2, varscan2
- RNF150 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100152769; called by muse, mutect2, varscan2
- RO60 | c.530G>C p.W177S | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100814301; called by muse, mutect2, varscan2
- ROBO1 | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1383299148, COSV101458229; called by muse, mutect2
- RTEL1 | c.3361C>A p.R1121S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV99422656; called by muse, mutect2, varscan2
- RTN4 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.014); catalogued as rs201003451, COSV100462580; called by muse, mutect2, varscan2
- RYR1 | c.7323+1G>T p.X2441_splice | Splice Site (SNP) | VAF 36/46 reads (78%) | catalogued as COSV100614052; called by muse, mutect2, varscan2
- SCAF1 | c.3451G>T p.V1151L | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.047); catalogued as rs1283325558, COSV100566751; called by muse, mutect2, varscan2
- SCARA5 | c.741C>G p.D247E | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV100107534; called by muse, mutect2, varscan2
- SCN4B | c.296A>T p.D99V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.239); catalogued as COSV100228559; called by muse, mutect2, varscan2
- SCN8A | c.20C>A p.A7E | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100632973; called by muse, mutect2, varscan2
- SDS | c.629T>G p.L210R | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.244); catalogued as COSV99980859; called by muse, mutect2, varscan2
- SEL1L3 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.759); catalogued as COSV53549699; called by muse, mutect2, varscan2
- SEMA4C | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs753800077, COSV100560659; called by muse, mutect2
- SEMA6D | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100316269; called by muse, mutect2, varscan2
- SEMA6D | c.2143G>T p.A715S (on ENST00000316364 / NM_153618.2; = p.A653S on NM_020858.2) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV100316271; called by muse, mutect2, varscan2
- SGIP1 | c.623del p.A208Vfs*11 | Frame Shift Del (DEL) | VAF 46/76 reads (61%) | catalogued as COSV99391583; called by mutect2, varscan2
- SGK2 | c.508T>C p.Y170H | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100414529; called by muse, mutect2, varscan2
- SI | c.2737-1G>T p.X913_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | catalogued as rs1294620045, COSV100013356; called by muse, mutect2
- SLC2A4 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV99142633; called by muse, mutect2, varscan2
- SLC38A10 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99917058; called by muse, mutect2, varscan2
- SLC8A1 | c.1337C>T p.T446I | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243913; called by muse, mutect2, varscan2
- SLC8A3 | c.1950G>C p.K650N (on ENST00000381269 / NM_183002.3; = p.K648N on NM_033262.4) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.445); catalogued as COSV53692703, COSV99385193; called by muse, mutect2, varscan2
- SLIT2 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99879751; called by muse, mutect2
- SMC4 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV100424225; called by muse, mutect2
- SMC6 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs763328076, COSV100704664; called by muse, mutect2, varscan2
- SNAP91 | c.2537G>A p.G846E | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52128461; called by muse, mutect2, varscan2
- SPANXN1 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV65123651; called by muse, mutect2, varscan2
- SPIC | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54691814; called by muse, mutect2, varscan2
- SRP72 | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 60/72 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100714223; called by muse, mutect2, varscan2
- SRPX2 | c.718C>A p.R240S | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT tolerated (0.24); PolyPhen benign (0.333); catalogued as COSV100883977, COSV65933194; called by muse, mutect2, varscan2
- STYXL2 | c.2532G>T p.Q844H | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV54805708; called by muse, mutect2, varscan2
- SYNE1 | c.21682G>C p.A7228P (on ENST00000367255 / NM_182961.4; = p.A7157P on NM_033071.3) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV99549628; called by muse, mutect2, varscan2
- SYNE2 | c.18551G>A p.R6184Q | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1420876581, COSV100646359; called by muse, mutect2, varscan2
- SYNJ2BP | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99832556; called by muse, mutect2, varscan2
- SYNPO2L | c.2149A>G p.M717V (on ENST00000394810 / NM_001114133.3; = p.M493V on NM_024875.5) | Missense Mutation (SNP) | VAF 94/159 reads (59%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1214059186, COSV100866271; called by muse, mutect2, varscan2
- TBX19 | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 42/550 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100892304; called by muse, mutect2
- TBX5 | c.511-1G>C p.X171_splice | Splice Site (SNP) | VAF 47/87 reads (54%) | catalogued as COSV100090191; called by muse, mutect2, varscan2
- TCL1A | c.154C>A p.R52S | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV101268434, COSV68085859; called by muse, mutect2, varscan2
- TDRD9 | c.2875G>C p.D959H | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV100174482, COSV59151667; called by muse, mutect2, varscan2
- TDRP | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV60706174; called by muse, mutect2, varscan2
- TGM6 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs865986592, COSV52478824, COSV99172922; called by muse, mutect2, varscan2
- THBD | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1163360332, COSV101001799; called by muse, mutect2, varscan2
- TM2D2 | c.410G>C p.R137P (on ENST00000456397 / NM_078473.3; = p.R94P on NM_031940.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100205528; called by muse, varscan2
- TMEM39B | c.1101C>G p.N367K | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100297803; called by muse, mutect2, varscan2
- TNNI2 | c.277-1G>T p.X93_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99425266; called by muse, mutect2, varscan2
- TPR | c.1014G>T p.M338I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV100823518; called by muse, mutect2, varscan2
- TPTE | c.1081A>G p.T361A (on ENST00000618007 / NM_199261.4; = p.T343A on NM_199259.4) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs763509744; called by muse, mutect2, varscan2
- TRDMT1 | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV100003708; called by muse, mutect2, varscan2
- TRIM36 | c.870T>C p.C290= | Splice Region (SNP) | VAF 28/37 reads (76%) | catalogued as COSV99142219; called by muse, mutect2, varscan2
- TRPA1 | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763236058, COSV51562825; called by muse, mutect2, varscan2
- TRPC4 | c.2330C>G p.S777* (on ENST00000379705 / NM_016179.4; = p.S782* on NM_003306.3) | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100155429; called by muse, mutect2, varscan2
- TRPV5 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.185); catalogued as COSV99519958; called by muse, mutect2
- TTN | c.72443T>A p.I24148K (on ENST00000591111; = p.I16724K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | PolyPhen benign (0.122); catalogued as COSV100588824; called by muse, mutect2, varscan2
- TTN | c.63438C>A p.S21146R (on ENST00000591111; = p.S13722R on NM_003319.4) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | PolyPhen possibly damaging (0.79); catalogued as COSV100588826; called by muse, mutect2, varscan2
- TTN | c.48227G>A p.R16076H (on ENST00000591111; = p.R8652H on NM_003319.4) | Missense Mutation (SNP) | VAF 129/558 reads (23%) | PolyPhen possibly damaging (0.814); catalogued as rs757018821, COSV60165224; called by muse, mutect2, varscan2
- TTN | c.3837G>T p.M1279I (on ENST00000591111; = p.M1233I on NM_003319.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | PolyPhen benign (0.003); catalogued as COSV100588829; called by muse, mutect2, varscan2
- TUBA1C | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.92); catalogued as COSV56510478, COSV99988594; called by muse, mutect2, varscan2
- TUBGCP6 | c.4733C>G p.S1578C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV50588847, COSV99954649; called by muse, mutect2, varscan2
- U2SURP | c.1642G>T p.G548* | Nonsense Mutation (SNP) | VAF 27/137 reads (20%) | catalogued as COSV101204294; called by muse, mutect2, varscan2
- UGT3A2 | c.1077T>A p.A359= | Splice Region (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99235883; called by muse, mutect2, varscan2
- UNC5D | c.2579G>C p.R860P | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54776215, COSV99771084; called by muse, mutect2, varscan2
- UTS2R | c.241C>A p.R81S | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs1352027900, COSV100493254, COSV57453207; called by muse, mutect2, varscan2
- VN1R4 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.6); catalogued as COSV100237279; called by muse, mutect2, varscan2
- WDR31 | c.148C>T p.Q50* (on ENST00000374193 / NM_001006615.3; = p.Q49* on NM_145241.5) | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100516569; called by mutect2, varscan2
- WDR36 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs778072785, COSV101540775; called by muse, mutect2, varscan2
- XIRP2 | c.7313G>C p.G2438A (on ENST00000628543; = p.G2613A on NM_152381.6) | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99736823; called by muse, mutect2, varscan2
- ZBTB20 | c.1729C>T p.P577S (on ENST00000474710 / NM_001164342.2; = p.P504S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as COSV100612392; called by muse, mutect2, varscan2
- ZCCHC3 | c.1034G>C p.S345T | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV101210821; called by muse, mutect2, varscan2
- ZFP36L1 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 128/298 reads (43%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); catalogued as COSV100322378; called by muse, mutect2, varscan2
- ZFPM2 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 31/64 reads (48%) | catalogued as COSV101022901; called by muse, mutect2, varscan2
- ZFYVE26 | c.2927A>T p.D976V | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100719943; called by muse, mutect2, varscan2
- ZMYND19 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 62/67 reads (93%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1235567418, COSV100057017; called by muse, mutect2, varscan2
- ZNF208 | c.1989G>T p.K663N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs879060240, COSV101236621; called by muse, varscan2
- ZNF208 | c.1013A>G p.E338G | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101236622; called by muse, varscan2
- ZNF423 | c.1151C>A p.A384D (on ENST00000563137 / NM_001379286.1; = p.A376D on NM_015069.4) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.233); catalogued as COSV99279189; called by muse, mutect2, varscan2
- ZNF462 | c.3026C>G p.P1009R | Missense Mutation (SNP) | VAF 100/196 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV99470486; called by muse, mutect2, varscan2
- ZNF492 | c.1138C>A p.L380I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV101513918; called by mutect2, varscan2
- ZNF559 | c.1138C>G p.P380A | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.626); catalogued as rs559787607, COSV100416353; called by muse, mutect2, varscan2
- ZNF618 | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.253); catalogued as rs201855820, COSV99928861; called by muse, mutect2, varscan2
- ZNF804B | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100301165; called by muse, mutect2, varscan2
- ZP4 | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV100850471; called by muse, mutect2, varscan2
- ACACB | c.4503_4513del p.E1501Dfs*3 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | called by mutect2, pindel
- ADD2 | c.845del p.C282Sfs*6 | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | called by mutect2, pindel, varscan2
- BBS9 | c.2200del p.V734* (on ENST00000242067 / NM_001348036.1; = p.V694* on NM_014451.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 60/226 reads (27%) | called by mutect2, pindel, varscan2
- BLZF1 | c.499del p.A167Lfs*14 | Frame Shift Del (DEL) | VAF 159/298 reads (53%) | called by mutect2, pindel, varscan2
- CCDC74A | c.471del p.D158Tfs*103 | Frame Shift Del (DEL) | VAF 11/111 reads (10%) | called by mutect2, pindel, varscan2
- CEP97 | c.1054del p.V352Lfs*3 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- CLEC4F | c.1097T>A p.M366K | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2
- DENND4B | c.1994_2035del p.P665_E678del | In Frame Del (DEL) | VAF 34/232 reads (15%) | called by mutect2, pindel
- DHX37 | c.2076_2078del p.F692_E693delinsL | In Frame Del (DEL) | VAF 11/82 reads (13%) | called by mutect2, pindel, varscan2
- FCHO1 | c.1123del p.A375Qfs*23 | Frame Shift Del (DEL) | VAF 47/143 reads (33%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 75/629 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGKV3-15 | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- IQGAP2 | c.2377C>A p.Q793K | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.366); called by muse, mutect2
- IRX2 | c.643del p.A215Qfs*69 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | called by mutect2, pindel, varscan2
- LRP12 | c.1135del p.E379Kfs*109 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- MRC1 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGB2 | c.1527_1528del p.Q510Efs*13 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | called by pindel, varscan2
- SGIP1 | c.627del p.F209Lfs*10 | Frame Shift Del (DEL) | VAF 43/113 reads (38%) | called by mutect2*, pindel, varscan2*
- SP100 | c.1634del p.G545Vfs*15 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- TEX13A | c.783del p.Q262Rfs*91 | Frame Shift Del (DEL) | VAF 20/32 reads (63%) | called by mutect2, pindel, varscan2
- VN1R5 | c.861C>G p.F287L | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZFAT | c.3596C>G p.S1199C | Missense Mutation (SNP) | VAF 2/15 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2
- ZNF410 | c.97_101del p.A33Rfs*12 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.1491C>A p.T497= (on ENST00000506720 / NM_001322402.2; = p.T429= on NM_015236.6) | Silent (SNP) | VAF 210/294 reads (71%) | catalogued as COSV72230065; called by muse, mutect2, varscan2
- AKNA | c.3441G>A p.E1147= | Silent (SNP) | VAF 83/95 reads (87%) | catalogued as rs145547019; called by muse, mutect2, varscan2
- ANO4 | c.1092T>A p.A364= (on ENST00000392977 / NM_001286615.2; = p.A329= on NM_178826.4) | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100151344; called by muse, mutect2, varscan2
- AP002512.3 | c.1035G>T p.G345= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99687654; called by muse, mutect2, varscan2
- ARMC4 | c.1608C>A p.G536= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100536082, COSV100537445; called by muse, mutect2, varscan2
- ASB13 | c.696C>T p.F232= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs144206251, COSV63090248; called by muse, mutect2
- ATP2A1 | c.696T>A p.I232= | Silent (SNP) | VAF 60/140 reads (43%) | catalogued as COSV63922965; called by muse, mutect2, varscan2
- AVPR1A | c.618C>A p.T206= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as COSV100146744; called by muse, mutect2, varscan2
- CDH11 | c.1605C>T p.I535= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as rs1286796479, COSV51756653, COSV99216774; called by muse, mutect2, varscan2
- CIITA | c.1734G>C p.V578= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV100161207; called by muse, mutect2, varscan2
- CISH | c.546G>A p.P182= (on ENST00000348721 / NM_145071.4; = p.P199= on NM_013324.6) | Silent (SNP) | VAF 36/47 reads (77%) | catalogued as rs78700237; called by muse, mutect2, varscan2
- CNGB1 | c.3540C>A p.A1180= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV99201329; called by muse, mutect2, varscan2
- CNTNAP1 | c.1269C>T p.I423= | Silent (SNP) | VAF 68/166 reads (41%) | catalogued as COSV52850189; called by muse, mutect2, varscan2
- COL1A2 | c.219C>A p.L73= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as COSV99798098; called by muse, mutect2, varscan2
- CRAMP1 | c.2388G>T p.P796= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99245466; called by muse, mutect2, varscan2
- DNAH5 | c.3948C>G p.V1316= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs369432984, COSV99443273; called by muse, mutect2, varscan2
- DNAJC6 | c.111A>G p.L37= | Silent (SNP) | VAF 57/79 reads (72%) | catalogued as COSV99673729; called by muse, mutect2, varscan2
- DRGX | c.426G>T p.T142= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100938279; called by muse, mutect2, varscan2
- DYSF | c.2451C>T p.S817= | Silent (SNP) | VAF 105/217 reads (48%) | catalogued as COSV50545209, COSV99243412; called by muse, mutect2, varscan2
- EDA2R | c.699C>A p.S233= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as COSV99490433; called by muse, mutect2, varscan2
- ENOX1 | c.237A>G p.P79= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV99814703; called by muse, mutect2, varscan2
- ESS2 | c.999G>A p.T333= | Silent (SNP) | VAF 107/227 reads (47%) | catalogued as rs764030211, COSV99350528; called by muse, mutect2, varscan2
- FAT3 | c.6099G>T p.G2033= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV99959892; called by muse, varscan2
- FBN2 | c.8406C>G p.P2802= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV52505164, COSV99324030; called by muse, mutect2, varscan2
- FLT3 | c.2559A>G p.K853= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV99606930; called by muse, mutect2, varscan2
- FRG2C | c.493C>T p.L165= | Silent (SNP) | VAF 85/134 reads (63%) | called by muse, mutect2, varscan2
- GABRA6 | c.966A>T p.A322= | Silent (SNP) | VAF 29/40 reads (73%) | catalogued as rs780168026, COSV99194001; called by muse, mutect2, varscan2
- GRIN2A | c.3921C>A p.P1307= | Silent (SNP) | VAF 62/141 reads (44%) | catalogued as COSV58023956; called by muse, mutect2, varscan2
- H2BC6 | c.96C>A p.R32= | Silent (SNP) | VAF 129/167 reads (77%) | catalogued as COSV100534354; called by muse, mutect2, varscan2
- HELLS | c.684A>G p.V228= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV99491634; called by muse, mutect2, varscan2
- HEPH | c.3228C>T p.T1076= (on ENST00000343002; = p.T809= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as COSV100293823; called by muse, mutect2, varscan2
- HHIPL2 | c.129C>A p.P43= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100596492; called by muse, varscan2
- IGHJ2 | c.33C>A p.T11= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs782409406; called by muse, mutect2, varscan2
- IGHV1-46 | c.102G>T p.G34= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as rs377180003; called by muse, mutect2, varscan2
- IMPG1 | c.1011T>C p.H337= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs1158491274, COSV100885709; called by muse, mutect2, varscan2
- ITIH5 | c.1233C>T p.V411= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs781569747, COSV53662512; called by muse, mutect2, varscan2
- ITPRID1 | c.2181G>T p.G727= | Silent (SNP) | VAF 46/173 reads (27%) | catalogued as rs372213107; called by muse, mutect2, varscan2
- KCNA6 | c.885C>A p.I295= | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as COSV54977148, COSV99768203; called by muse, mutect2, varscan2
- KCNQ2 | c.519C>T p.I173= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs1382985236, COSV100609157; called by muse, mutect2
- KCTD17 | c.306C>T p.D102= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs1245911153, COSV100786745; called by muse, mutect2, varscan2
- KDM5A | c.4944T>A p.A1648= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV66996845; called by muse, mutect2, varscan2
- KIF2B | c.459C>A p.I153= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as COSV52126705, COSV52127659, COSV99274436; called by muse, mutect2
- LAMC2 | c.2748G>C p.G916= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV51454389, COSV99916867; called by muse, mutect2, varscan2
- LRRC4C | c.177G>A p.K59= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV99536540; called by muse, mutect2, varscan2
- LRRTM1 | c.1398G>T p.T466= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV99701539; called by muse, mutect2, varscan2
- MARCHF10 | c.945A>G p.K315= | Silent (SNP) | VAF 138/356 reads (39%) | catalogued as COSV100247732; called by muse, mutect2
- MAVS | c.570G>A p.L190= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100816205, COSV63927136; called by muse, mutect2
- MFHAS1 | c.1945C>A p.R649= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV99359054; called by muse, mutect2, varscan2
- MMRN2 | c.2277A>G p.Q759= | Silent (SNP) | VAF 47/89 reads (53%) | catalogued as COSV100922449; called by muse, mutect2, varscan2
- MSH4 | c.1188G>A p.E396= | Silent (SNP) | VAF 21/30 reads (70%) | catalogued as COSV99590291; called by muse, mutect2, varscan2
- MUC16 | c.921C>A p.T307= | Silent (SNP) | VAF 66/157 reads (42%) | catalogued as COSV101197351; called by muse, mutect2, varscan2
- MUC3A | c.9201C>T p.F3067= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs1483818759, COSV100113772; called by muse, mutect2, varscan2
- MYLK4 | c.927T>A p.A309= | Silent (SNP) | VAF 33/48 reads (69%) | catalogued as COSV99193687; called by muse, mutect2, varscan2
- NAA10 | c.168C>G p.V56= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as COSV100892357; called by muse, mutect2
- NDST4 | c.216C>T p.D72= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99995082; called by muse, mutect2, varscan2
- NEFL | c.303C>T p.F101= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs748796725, COSV99647780; called by muse, mutect2
- NINL | c.2502G>T p.L834= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV99624263; called by muse, mutect2, varscan2
- NLRP12 | c.309G>T p.P103= | Silent (SNP) | VAF 38/51 reads (75%) | catalogued as COSV100144671, COSV60754093; called by muse, mutect2, varscan2
- NRF1 | c.1155G>A p.L385= | Silent (SNP) | VAF 52/85 reads (61%) | catalogued as COSV99781339; called by muse, mutect2, varscan2
- NRXN1 | c.1005G>A p.L335= | Silent (SNP) | VAF 29/279 reads (10%) | catalogued as rs1207288960, COSV100452563, COSV100453539; called by muse, mutect2, varscan2
- NXPE4 | c.1524G>A p.V508= (on ENST00000375478 / NM_001077639.2; = p.V224= on NM_017678.3) | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs779615426, COSV100970270; called by muse, mutect2, varscan2
- OBSCN | c.2034C>T p.H678= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs766782398, COSV99470784; called by muse, mutect2, varscan2
- OR10A5 | c.84C>T p.L28= | Silent (SNP) | VAF 74/204 reads (36%) | catalogued as COSV100203341; called by muse, mutect2, varscan2
- OR10G4 | c.441T>A p.T147= | Silent (SNP) | VAF 94/200 reads (47%) | catalogued as COSV57976504; called by muse, mutect2, varscan2
- OR2D2 | c.225C>A p.T75= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV100203685; called by muse, mutect2, varscan2
- OR2W3 | c.102G>T p.A34= | Silent (SNP) | VAF 64/128 reads (50%) | catalogued as COSV100831561; called by muse, varscan2
- OR4C46 | c.753C>G p.P251= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs753800053, COSV100060318, COSV60218441; called by muse, mutect2, varscan2
- OR4K1 | c.687C>G p.S229= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV99578516; called by muse, mutect2, varscan2
- OR5K4 | c.945A>C p.A315= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV100721280, COSV61584017; called by muse, mutect2
- OR6N1 | c.160C>A p.R54= | Silent (SNP) | VAF 55/114 reads (48%) | catalogued as COSV58647450, COSV58648204; called by muse, mutect2, varscan2
- PAPPA2 | c.603G>T p.V201= | Silent (SNP) | VAF 206/315 reads (65%) | catalogued as COSV100866404; called by muse, mutect2, varscan2
- PCDHGA3 | c.1977G>T p.T659= | Silent (SNP) | VAF 48/82 reads (59%) | catalogued as rs769439885, COSV53919702, COSV99528155; called by muse, mutect2, varscan2
- PDE1A | c.105A>G p.L35= | Silent (SNP) | VAF 56/81 reads (69%) | catalogued as rs142681796; called by muse, mutect2, varscan2
- PGLYRP2 | c.57G>A p.G19= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV99483680; called by muse, mutect2, varscan2
- PIGM | c.939C>T p.L313= | Silent (SNP) | VAF 59/312 reads (19%) | catalogued as rs758598643, COSV63636014; called by muse, mutect2, varscan2
- PIK3C2G | c.2733T>C p.D911= (on ENST00000676171; = p.D870= on NM_004570.5) | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV99848609; called by muse, varscan2
- PIP4K2B | c.267G>T p.L89= | Silent (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- PKHD1 | c.5395C>T p.L1799= | Silent (SNP) | VAF 25/231 reads (11%) | catalogued as COSV100580708; called by muse, mutect2, varscan2
- PLCH1 | c.2418G>A p.L806= (on ENST00000340059 / NM_001130960.2; = p.L818= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV100395311; called by muse, mutect2, varscan2
- POGLUT2 | c.201C>T p.G67= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs774195435, COSV99958452; called by muse, mutect2, varscan2
- PRTFDC1 | c.144C>T p.I48= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100196618, COSV100196752; called by muse, mutect2, varscan2
- PSMC4 | c.708A>T p.V236= | Silent (SNP) | VAF 44/62 reads (71%) | catalogued as COSV99338058; called by muse, mutect2, varscan2
- RAB39A | c.78C>T p.H26= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs1275157090, COSV100269013; called by muse, mutect2, varscan2
- RALYL | c.156C>T p.S52= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs534853015, COSV72826155; called by muse, mutect2, varscan2
- RASA4 | c.45G>A p.K15= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV99499727; called by muse, mutect2
- RASGRF1 | c.2319C>A p.A773= | Silent (SNP) | VAF 58/64 reads (91%) | catalogued as COSV101174226; called by muse, mutect2, varscan2
- RHBDD3 | c.126G>A p.E42= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99328379; called by muse, mutect2, varscan2
- RIF1 | c.27C>G p.L9= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99689858; called by muse, mutect2, varscan2
- SATB2 | c.2025G>A p.K675= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as rs759621584, COSV53493893, COSV99610386; called by muse, mutect2, varscan2
- SEMA4C | c.558C>T p.G186= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV100560661; called by muse, mutect2
- SERPINE1 | c.372G>C p.R124= | Silent (SNP) | VAF 140/443 reads (32%) | catalogued as COSV99776503; called by muse, mutect2, varscan2
- SLC13A5 | c.663C>T p.T221= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as rs373831482; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC14A1 | c.1083G>A p.K361= | Silent (SNP) | VAF 46/87 reads (53%) | catalogued as COSV100424700; called by muse, mutect2, varscan2
- SLC25A32 | c.172C>T p.L58= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV99884122; called by muse, mutect2, varscan2
- SLC52A2 | c.978C>T p.F326= | Silent (SNP) | VAF 77/168 reads (46%) | catalogued as rs1272142641, COSV100095394; called by muse, mutect2, varscan2
- SLITRK5 | c.2085C>T p.N695= | Silent (SNP) | VAF 44/67 reads (66%) | catalogued as COSV100280071; called by muse, mutect2, varscan2
- SPOCK1 | c.117A>T p.L39= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99967561; called by muse, mutect2, varscan2
- SPTAN1 | c.4587C>G p.V1529= | Silent (SNP) | VAF 10/260 reads (4%) | catalogued as COSV100823135; called by muse, mutect2
- STRADA | c.1242C>A p.I414= (on ENST00000336174 / NM_001363786.1; = p.I377= on NM_001003786.3) | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs774261799, COSV51991279; called by muse, mutect2, varscan2
- STRN | c.996C>G p.L332= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs972695014, COSV55747790; called by muse, mutect2, varscan2
- SUMF1 | c.27G>T p.V9= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV99794351; called by muse, mutect2, varscan2
- TAS2R41 | c.234G>T p.G78= | Silent (SNP) | VAF 68/132 reads (52%) | catalogued as COSV101281464; called by muse, mutect2, varscan2
- TMEM132B | c.954G>A p.A318= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs1348467148, COSV54770807; called by muse, mutect2, varscan2
- TNPO2 | c.1974G>A p.Q658= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100790254; called by muse, varscan2
- TRAV10 | c.138T>C p.Y46= | Silent (SNP) | VAF 40/58 reads (69%) | catalogued as rs778001877; called by muse, mutect2, varscan2
- TRAV16 | c.329G>T p.*110= | Silent (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2, varscan2
- TRO | c.750C>A p.A250= | Silent (SNP) | VAF 29/32 reads (91%) | catalogued as COSV99435506; called by muse, mutect2, varscan2
- TSPAN15 | c.222C>T p.F74= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100960192; called by muse, mutect2, varscan2
- USH2A | c.13923G>A p.E4641= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100227501; called by muse, mutect2, varscan2
- VWA3B | c.2589T>C p.D863= | Silent (SNP) | VAF 69/152 reads (45%) | catalogued as COSV101345893; called by muse, mutect2, varscan2
- YTHDF3 | c.330G>C p.G110= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV101572347; called by muse, mutect2, varscan2
- ZFAT | c.3597C>T p.S1199= | Silent (SNP) | VAF 2/17 reads (12%) | catalogued as rs927243708, COSV64734361; called by muse, mutect2
- ZFP42 | c.888C>A p.I296= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV100478509, COSV58816533; called by muse, mutect2, varscan2
- ZNF239 | c.102A>G p.G34= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100021674; called by muse, mutect2, varscan2
- ZNF423 | c.3306C>A p.G1102= (on ENST00000563137 / NM_001379286.1; = p.G1094= on NM_015069.4) | Silent (SNP) | VAF 37/50 reads (74%) | catalogued as COSV99279186; called by muse, mutect2, varscan2
- ZNF558 | c.741C>T p.T247= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV56862313; called by muse, mutect2, varscan2
- ZNF829 | c.579T>C p.F193= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as COSV101199540; called by muse, mutect2, varscan2
- ZNF831 | c.1521G>A p.L507= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs1245609327, COSV100925690; called by muse, mutect2, varscan2
- DCHS2 | n.8357G>T | RNA (SNP) | VAF 48/70 reads (69%) | catalogued as rs753533849, COSV100600862; called by muse, mutect2, varscan2
- DCHS2 | n.6136T>A | RNA (SNP) | VAF 16/19 reads (84%) | catalogued as COSV100600864; called by muse, mutect2, varscan2
- GIT1 | c.*57G>C | 3'UTR (SNP) | VAF 16/118 reads (14%) | catalogued as COSV99837783; called by muse, mutect2, varscan2
- LHFPL3 | c.-30G>T | 5'UTR (SNP) | VAF 22/32 reads (69%) | catalogued as rs987503596, COSV101308042, COSV101308463; called by muse, varscan2
- MFRP | chr11:119345784 G>A | 5'Flank (SNP) | VAF 34/106 reads (32%) | catalogued as COSV100793278; called by muse, mutect2, varscan2
- MIR517A | n.32T>G | RNA (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.*2G>T | 3'UTR (SNP) | VAF 30/146 reads (21%) | catalogued as COSV99301464; called by muse, mutect2, varscan2
- RASSF10 | c.-170G>C | 5'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
